Surgical pathology report (de-identified scan), TCGA case TCGA-3B-A9HR, project TCGA-SARC (Sarcoma), tissue source site Moffitt Cancer Center, specimen TCGA-3B-A9HR-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Gender: F
Reported:
Submitting Physicians:
Pathologist: MD, PhD
Intraop Pathologist:
Performing Physician:
Received:

CLINICAL HISTORY:

-YEAR-OLD FEMALE WITH BIOPSY-PROVEN LEIOMYOSARCOMA, LEFT THIGH.

PREOPERATIVE DIAGNOSIS:

LEFT KNEE MASS.

SPECIMEN TYPE(S):

A: LEFT KNEE MASS

FINAL DIAGNOSIS:

A. LEFT KNEE SOFT TISSUE MASS, RESECTION: Moderate to high-grade
leiomyosarcoma (see key pathologic findings).

KEY PATHOLOGICAL FINDINGS:

Operation performed:	Resection.
Tumor location:	Left knee.
Diagnosis:	Leiomyosarcoma.
Tumor Grade:	Moderate to high grade.
Tumor size:	8.0 x 6.5 x 4.0 cm.
Encapsulation:	Partially.
Tumor necrosis:	15%.
Cellular morphology:	Spindle and pleomorphic.
Mitosis:	5-6 mitoses per 10 high-power field (50 fields counted).
Margin status:	Free of tumor. The closest medial and posterior margins
1	defined by fibrous pseudocapsule.

reportable.

I, MD, PhD the attending pathologist, personally reviewed the entire pathology case and rendered the final diagnosis. Electronically signed out by

OTHER RELATED CLINICAL DATA:

NA

GROSS DESCRIPTION:

A. Specimen A is received fresh labeled "left knee mass." The specimen consists of an irregular, tan-yellow fragment of soft tissue measuring 8.0 x 6.5 x 4.0 cm. The specimen has been oriented by the surgeon as follows: A stitch marks distal-medial margin. The specimen is inked as follows:
Superior-proximal margin: Black.
Inferior-distal margin: Blue.
Medial margin: Red.
Lateral margin: Yellow.
Anterior-superficial margin: Green.
Posterior-deep margin: Orange.

ICD O-3
Leiomyosarcoma NOS 8890/3
Site: (L) thigh NOS C49.2
JW 4/22/14

[page 2 of 2]
The specimen is serially sectioned to reveal a tan-white to tan-yellow, multilobulated mass measuring 8.0 cm in greatest diameter. The lesion is well defined by a thin fibroconnective pseudocapsule located at 0.1 cm from medial and deep-posterior margin of resection. There are areas of necrosis present (15%). Representative fresh tissue is submitted to the tissue procurement laboratory. Representative sections are submitted as follows:

- A1: Perpendicular section proximal margin of resection.
- A2: Perpendicular section distal margin of resection.
- A3: Perpendicular section superficial margin of resection.
- A4: Perpendicular section deep margin of resection.
- A5: Lesion in relation to medial and lateral margins of resection.
- A6-A10: Random sections of the lesion.

Source: NCI Genomic Data Commons file 9412294d-30bd-49db-b0ec-c605ba973059 (TCGA-3B-A9HR.8760B5EC-6523-4330-8313-6D810994DE3F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).